Gene-level copy-number profile of tumor specimen TCGA-25-1870-01A from TCGA case TCGA-25-1870, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 59.0 years (21,550 days).
Specimen TCGA-25-1870-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d86ee094-af3a-4be2-9ac6-35f6cc825ebb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1870-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/00d4dd9f-fa39-43fc-896d-a79ac7ee1a50

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 24; copy number 2: 658; copy number 3: 7,910; copy number 4: 16,234; copy number 5: 13,983; copy number 6: 10,049; copy number 7: 3,460; copy number 8: 5,067; copy number 9: 404; copy number 10: 700; copy number 11: 220; copy number 12: 363; copy number 13: 188; copy number 14: 18; copy number 15: 202; copy number 16: 6; copy number 17: 19; copy number 18: 2; copy number 19: 38; copy number 20: 64; copy number 22: 44; copy number 23: 24; copy number 24: 3; copy number 29: 7; copy number 30: 26; copy number 37: 11; copy number 39: 9; copy number 45: 7; copy number 48: 16; copy number 52: 1; copy number 59: 14; copy number 63: 46; copy number 65: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1870-01): tumor purity 0.86, ploidy 5.15, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,246 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–151,583,583, 322 genes, copy number 9–13 (within-gene range 8–13) (broad region; genes not listed).
- chr1:159,276,503–163,923,873, 174 genes, copy number 10 (broad region; genes not listed).
- chr1:198,450,666–199,909,648, 21 genes, copy number 9: AL450352.1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1, LINC02789, RPL23AP16, AC099335.1, AL596266.1, AL445687.1, RNU6-778P, AL445687.2.
- chr1:200,478,020–208,270,667, 250 genes, copy number 9–12 (broad region; genes not listed).
- chr1:208,697,369–212,107,400, 72 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr1:220,359,731–220,885,059, 19 genes, copy number 9: AL451081.1, AC096644.3, AC096644.2, AC096644.1, PRELID3BP1, LINC02779, MARK1, RN7SL464P, HDAC1P2, C1orf115, MTARC2, MTARC1, AL445423.3, RNU6ATAC35P, AL445423.2, AL445423.1, LINC01352, HLX-AS1, HLX.
- chr1:230,002,372–235,344,532, 115 genes, copy number 10 (broad region; genes not listed).
- chr1:235,336,806–235,337,087, 1 gene, copy number 10: AL391994.1.
- chr1:244,352,635–248,919,946, 163 genes, copy number 10 (broad region; genes not listed).
- chr3:62,779,176–62,814,491, 3 genes, copy number 18–52: AC012519.1, RN7SL863P, RNU6-139P.
- chr3:86,481,943–87,324,723, 9 genes, copy number 39: LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25.
- chr3:96,566,357–99,018,562, 57 genes, copy number 9: AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6, AC117470.1, AC110491.1, ARL6, AC110491.3, CRYBG3, AC110491.2, RIOX2, AC026100.1, GABRR3, OR5BM1P, OR5AC1, OR5AC2, AC117460.1, OR5AC4P, POU5F1P7, OR5H1, OR5H14, OR5H15, OR5H5P, OR5H3P, OR5H4P, AC117473.1, OR5H7P, OR5H6, OR5H2, OR5H8, OR5K4, OR5K3, UBFD1P1, OR5K1, OR5K2, CLDND1, AC021660.3, AC021660.2, RPL38P4, GPR15, AC021660.4, CPOX, AC021660.1, WWP1P1, ST3GAL6-AS1, ST3GAL6, PDLIM1P4, DCBLD2, RNU6-26P, AC091212.1, RNU6-1263P, LINC00973, U7.
- chr3:193,957,372–198,222,513, 160 genes, copy number 11 (broad region; genes not listed).
- chr4:138,923,930–139,740,745, 27 genes, copy number 10: AC109927.2, NOCT, ELF2, RNU6-531P, RN7SL382P, PPP1R14BP3, Metazoa_SRP, RN7SL311P, Y_RNA, RNU6-506P, RNU6-1074P, MGARP, NDUFC1, NAA15, RNU6-1214P, AC097376.3, AC097376.2, AC097376.1, RAB33B, SETD7, FTH1P24, AC112236.2, AC112236.3, AC112236.1, MGST2, RN7SKP237, H3P16.
- chr4:139,763,080–139,794,433, 2 genes, copy number 10: AC108053.1, RN7SKP253.
- chr4:142,286,917–142,287,625, 1 gene, copy number 9: RPL5P13.
- chr12:1,380,060–4,405,490, 79 genes, copy number 15–59 (within-gene range 6–59) (broad region; genes not listed).
- chr12:5,290,480–8,218,911, 142 genes, copy number 9–14 (within-gene range 6–14) (broad region; genes not listed).
- chr12:9,624,122–12,568,776, 112 genes, copy number 10–30 (broad region; genes not listed).
- chr12:13,238,582–13,387,167, 2 genes, copy number 11: AC022276.1, LINC01559.
- chr12:13,440,884–13,683,886, 6 genes, copy number 16: RNA5SP353, RNU6-590P, AC007527.1, AC007527.2, AC007535.1, RN7SKP162.
- chr12:20,695,332–25,648,579, 75 genes, copy number 12–63 (broad region; genes not listed).
- chr12:45,718,046–46,004,685, 7 genes, copy number 13: AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1.
- chr13:29,509,414–29,850,617, 2 genes, copy number 11 (within-gene range 6–11): SLC7A1, UBL3.
- chr19:15,107,401–19,628,930, 251 genes, copy number 11–22 (broad region; genes not listed).
- chr19:22,518,414–22,716,991, 17 genes, copy number 29–30: AC011467.6, AC011467.1, LINC01233, RNU6-1179P, AC011467.5, GOLGA2P9, RN7SL860P, AC011467.3, AC011467.4, RAD54L2P1, LINC01785, AC011467.2, ZNF492, AC024563.1, ZNF849P, RPL34P33, AC024563.2.
- chr19:23,221,599–24,163,425, 38 genes, copy number 19: ZNF724, AC092329.3, BNIP3P38, IPO5P1, AC092329.1, AC092329.4, VN1R90P, VN1R91P, ZNF91, AC010300.1, BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr19:34,758,073–36,331,770, 119 genes, copy number 9–65 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
